CPTAC case C3N-03417 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/64484b08-080b-4a27-a082-aaa7a05da656

Demographics
Sex at birth: female; Race: white; Year of birth: 1950; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Endometrium; Age at diagnosis: 67.8 years (24,766 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,768 days (4.8 years); Progression or recurrence: no; Days to last follow up: 1,768 days (4.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.7 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 5; Margin status: Uninvolved.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 346 days; Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 710 days (1.9 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,103 days (3.0 years); Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,103 days (3.0 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,432 days (3.9 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,768 days (4.8 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.

Other clinical attributes
- Weight: 83 kg; Height: 165 cm; BMI: 30.49; Hormonal contraceptive use: Never Used.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03417-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 207 mg; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03417-21: Section location: Posterior endometrium; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3N-03417-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03417-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
